Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A167, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A167-01A (Primary Tumor).

[page 1 of 2]
Adenocarcinoma, Endometrioid, NOS

8380/3 12/9/10

Surgical Pathology Site Code: Endometrium ^{per} C54.1

TISSUE DESCRIPTION:

A1 A2 A3 A4 A5 A6 A7 A8 A9 A10 A11 A12 A13 B1 B2
B3 B4 B5
B6 B7 B8 B9 C1 C2 C3 C4 C5 C6 C7 C8 C9 C10 C11 D1 E1 E2 F1
G1 H1 H2
I1

Uterus, right ovary (1.9 x 0.9 x 0.8 cm) with 9.6 cm
segment of
right fallopian tube, and left ovary (1.8 x 1.1 x 0.7 cm)
with 8.8
cm segment of left fallopian tube (together weighing 130.0
grams);
right and left pelvic lymph nodes; right and left para-
aortic lymph
nodes above and below the inferior mesenteric artery;
right gonadal
vessel (6.2 cm in length); and left gonadal vessel (5.4 cm
in
length).

DIAGNOSIS:

Uterus, bilateral ovaries, and fallopian tubes; total
abdominal
hysterectomy and bilateral salpingo-oophorectomy:
Endometrial
adenocarcinoma, endometrioid type with villoglandular
features, FIGO
grade 2 (of 3) forming a polypoid mass (5.4 x 3.7 x 2.6 cm)
that
invades 1.3 cm into the myometrium (total myometrial
thickness, 2.1
cm). There is no lymphovascular invasion. The cervix is
uninvolved. The bilateral ovaries and fallopian tubes are
without
diagnostic abnormality.

Lymph nodes, left pelvic, excision: Multiple (4 external
iliac, 2
internal iliac, 2 common iliac, 9 obturator) left pelvic
lymph nodes
are negative for tumor.

[page 2 of 2]
Lymph nodes, right pelvic, excision: Multiple (7 external iliac, 4 internal iliac, 8 common iliac, 16 obturator) right pelvic lymph nodes are negative for tumor.

Lymph nodes, left and right para-aortic, excision: Multiple (9 left, 4 right) para-aortic lymph nodes above the inferior mesenteric artery are negative for tumor. Multiple (5 left, 2 right) para-aortic lymph nodes below the inferior mesenteric artery are negative for tumor.

Gonadal vessels, left and right, excision: The left and right gonadal vessels are negative for tumor.

Source: NCI Genomic Data Commons file 5d5d5663-a753-48d4-9ebe-ffac80a1ec0f (TCGA-D1-A167.4E67EAA4-3069-4B62-A403-9300A9FA494C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).